Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A4XI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A4XI-01A (Primary Tumor).

Gross Description: Tumor is moderate-margins with 3x3x2cm in size, firm, solid, yellow-white , focal necrotic in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns, or tubular or acinar or sheets patterns intervening in benign tissue. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are abundant and the cytoplasm is eosinophilic or clear or vacuolated. Nuclei are very irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is necrotic and invasion of lymphocyte.

Diagnosis Details: Hepatocellular carcinoma, poorly-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 3 x 3 x 2 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, hepatocellular, NOS 8170/3
Site: liver, NOS C22.0

JW
10/23/12

Diagnosis Uncertainty		
HIST/AA Discrepancy		

JW 10/23/12

Source: NCI Genomic Data Commons file 571bab3e-c0a7-4c01-9a5e-07b5d27ad3a1 (TCGA-ED-A4XI.40130FAC-455F-49B7-A97E-CFFED2202925.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).